Somatic mutation profile of tumor specimen 0DWYWU from CCDI case PBCPMU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,467 days).
Specimen 0DWYWU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ac0ee05-d017-4168-9ce7-d98ebc32458f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad57da13-d59a-46c6-9f30-13d9eaff5be1

The open-access MAF lists 58 somatic variants for this specimen: 36 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, 3'UTR 5, Nonsense Mutation 5, Intron 3, 5'Flank 1, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D1 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 29/280 reads (10%) | catalogued as COSV100666566; called by muse, mutect2, varscan2
- DENND5A | c.3586C>T p.R1196W | Missense Mutation (SNP) | VAF 143/323 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs546431984, COSV60238450; called by muse, mutect2, varscan2
- FAT3 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 49/339 reads (14%) | catalogued as rs1230731830, COSV53074844; called by muse, mutect2, varscan2
- FMOD | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 179/909 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774641258; called by muse, mutect2, varscan2
- GPR161 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 96/575 reads (17%) | catalogued as rs961642617, COSV54788550; called by muse, mutect2, varscan2
- GRID2 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs758779402, COSV56175461; called by muse, mutect2, varscan2
- HEATR1 | c.3466G>A p.V1156I | Missense Mutation (SNP) | VAF 114/613 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs781305437; called by muse, mutect2, varscan2
- ITIH6 | c.2993G>C p.S998T | Missense Mutation (SNP) | VAF 169/202 reads (84%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54487318; called by muse, mutect2, varscan2
- KLF13 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56148217; called by muse, mutect2, varscan2
- KRT37 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 154/534 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs199801131; called by muse, mutect2
- LAMB4 | c.5096C>T p.A1699V | Missense Mutation (SNP) | VAF 149/495 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs189681685, COSV52713639; called by muse, mutect2, varscan2
- MYH13 | c.4786C>T p.R1596W | Missense Mutation (SNP) | VAF 86/121 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199949513, COSV52833716; called by muse, mutect2, varscan2
- MYL4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 169/568 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs745710105; called by muse, mutect2, varscan2
- NUP188 | c.4386C>A p.F1462L | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as rs1318942078; called by muse, mutect2
- OPLAH | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 82/789 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782469088; called by muse, mutect2, varscan2
- PCDHB7 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.407); catalogued as COSV50755714; called by muse, mutect2
- PTPRK | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 139/358 reads (39%) | catalogued as COSV63890946, COSV63892601; called by muse, mutect2, varscan2
- TCF12 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 120/228 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs771571672, COSV51004691; called by muse, mutect2, varscan2
- TTN | c.76289A>G p.K25430R (on ENST00000591111; = p.K18006R on NM_003319.4) | Missense Mutation (SNP) | VAF 235/464 reads (51%) | PolyPhen benign (0.234); catalogued as rs762539699; called by muse, mutect2, varscan2
- VAMP5 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 164/321 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs193102078; called by muse, mutect2, varscan2
- WARS1 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 166/382 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs1314683284, COSV59927626; called by muse, mutect2, varscan2
- ZSWIM4 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 108/632 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1364638272; called by muse, mutect2, varscan2
- AL662899.2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 126/407 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALAS2 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKRD30A | c.3087G>C p.L1029F (on ENST00000611781; = p.L973F on NM_052997.2) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AWAT1 | c.53G>A p.W18* | Nonsense Mutation (SNP) | VAF 39/248 reads (16%) | called by muse, mutect2, varscan2
- CTDNEP1 | c.321dup p.V108Cfs*3 | Frame Shift Ins (INS) | VAF 120/168 reads (71%) | called by mutect2, pindel, varscan2
- CUBN | c.8255G>T p.G2752V | Missense Mutation (SNP) | VAF 77/396 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GALNT10 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 227/725 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HLA-E | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- KCNH8 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 140/324 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAMA1 | c.2554A>G p.S852G | Missense Mutation (SNP) | VAF 150/492 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MDFIC | c.502G>T p.V168F | Missense Mutation (SNP) | VAF 58/457 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NYAP2 | c.421C>A p.P141T | Missense Mutation (SNP) | VAF 132/254 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHM1 | c.1903T>G p.W635G | Missense Mutation (SNP) | VAF 90/295 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR31 | c.1010T>A p.I337N (on ENST00000374193 / NM_001006615.3; = p.I336N on NM_145241.5) | Missense Mutation (SNP) | VAF 161/350 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CUBN | c.8253T>C p.N2751= | Silent (SNP) | VAF 75/397 reads (19%) | called by muse, mutect2
- HNRNPCL2 | c.429G>A p.S143= | Silent (SNP) | VAF 225/535 reads (42%) | catalogued as rs767487977, COSV60403518; called by muse, mutect2
- KIF14 | c.1251C>T p.Y417= | Silent (SNP) | VAF 139/601 reads (23%) | catalogued as rs199789511; called by muse, mutect2, varscan2
- LRGUK | c.981C>A p.P327= | Silent (SNP) | VAF 124/488 reads (25%) | catalogued as rs1440292691; called by muse, mutect2, varscan2
- LRP5 | c.339C>T p.L113= | Silent (SNP) | VAF 98/292 reads (34%) | catalogued as rs753488677, COSV99591465; called by muse, mutect2, varscan2
- MAGEA9B | c.798G>A p.A266= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1314159782; called by mutect2, varscan2
- SCN1A | c.2685C>T p.L895= (on ENST00000303395 / NM_001202435.3; = p.L884= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 145/338 reads (43%) | catalogued as rs771662215, COSV57661563; called by muse, mutect2, varscan2
- SLC27A1 | c.579C>T p.S193= | Silent (SNP) | VAF 223/413 reads (54%) | catalogued as rs747951000; called by muse, mutect2, varscan2
- TIE1 | c.177G>A p.P59= | Silent (SNP) | VAF 104/176 reads (59%) | catalogued as COSV65251287; called by muse, mutect2, varscan2
- UBE3B | c.1686T>C p.T562= | Silent (SNP) | VAF 135/321 reads (42%) | catalogued as rs756757808; called by muse, mutect2, varscan2
- WDR7 | c.2868C>T p.S956= | Silent (SNP) | VAF 39/217 reads (18%) | catalogued as rs188720836, COSV54348323; called by muse, mutect2, varscan2
- BPIFB2 | c.*75A>G | 3'UTR (SNP) | VAF 63/114 reads (55%) | called by muse, mutect2, varscan2
- CLCN3 | c.161-19646A>G | Intron (SNP) | VAF 99/210 reads (47%) | called by muse, mutect2, varscan2
- KHK | c.210-253G>A | Intron (SNP) | VAF 139/291 reads (48%) | catalogued as rs780961189; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF5C | c.292-1271C>G | Intron (SNP) | VAF 42/71 reads (59%) | called by muse, mutect2, varscan2
- MANSC1 | c.-18A>G | 5'UTR (SNP) | VAF 6/174 reads (3%) | called by muse, mutect2
- POMGNT1 | c.*396G>T | 3'UTR (SNP) | VAF 25/442 reads (6%) | called by muse, mutect2
- REEP5 | chr5:112922285 C>A | 5'Flank (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- RPS6KA2 | c.*11C>A | 3'UTR (SNP) | VAF 40/128 reads (31%) | called by muse, mutect2, varscan2
- RTBDN | c.*38C>A | 3'UTR (SNP) | VAF 66/417 reads (16%) | called by muse, mutect2, varscan2
- SSPOP | n.8789G>T | RNA (SNP) | VAF 132/467 reads (28%) | called by muse, mutect2, varscan2
- YPEL2 | c.*96C>G | 3'UTR (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
